CCDI case PBCSWK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/ad4efcde-7d77-4e41-b1cf-49c0c29f86c0

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 22.2 years (8,112 days).

Biospecimens (3 samples)
- Sample 0DYUZ0: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DYV0X: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DYV1C: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
